Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4839, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4839-01A (Primary Tumor).

FINAL DIAGNOSIS

TCGA-B0-4839

KIDNEY, LEFT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN GRADE 2 OF 4, 4.5 CM IN GREATEST DIMENSION.
- B. SURGICAL MARGINS ARE FREE OF TUMOR.
- C. THE TUMOR IS CONFINED TO THE KIDNEY, WITH NO EVIDENCE OF INVASION INTO RENAL SINUS OR PERINEPHRIC ADIPOSE TISSUE.
- D. ANGIOLYMPHATIC INVASION IS NOT PRESENT; THE RENAL VEIN IS FREE OF TUMOR.
- E. INCIDENTAL PAPILLARY RENAL CORTICAL NEOPLASMS, THREE, THE LARGEST 0.3 CM IN GREATEST DIMENSION.
- F. NON-NEOPLASTIC KIDNEY WITH MILD CHRONIC INTERSTITIAL NEPHRITIS, FOCAL GLOBAL GLOMERULOSCLEROSIS, MODERATE ARTERIAL AND ARTERIOLAR SCLEROSIS, AND SIMPLE RENAL CORTICAL CYSTS.
- G. PATHOLOGIC TNM STAGING: pT1b Nx Mx.

Source: NCI Genomic Data Commons file 8ac0886b-c4f6-40ad-892c-7de077954abe (TCGA-B0-4839.1857D79E-27A0-4BA4-8E11-CD23D92DCB7F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).